Somatic mutation profile of tumor specimen d154d194-2b08-46d4-a199-84cfb8 (aliquot d154d194-2b08-46d4-a199-84cfb8_D6) from CPTAC case 01BR018, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.0 years (24,089 days).
Specimen d154d194-2b08-46d4-a199-84cfb8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6efbb6fb-dfab-4ff2-8f67-bdf9fdf0c4d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f0359550-c332-466b-badd-310292 (Blood Derived Normal), aliquot f0359550-c332-466b-badd-310292_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd3aa50d-72d6-44f5-9aa6-5f9069fd085f

The open-access MAF lists 343 somatic variants for this specimen: 256 protein-altering or splice-affecting, 52 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 211, Silent 52, Intron 19, Frame Shift Del 16, In Frame Del 10, Nonsense Mutation 8, Splice Site 6, 3'Flank 5, RNA 4, 3'UTR 4, In Frame Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.3638G>T p.G1213V | Missense Mutation (SNP) | VAF 132/534 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559455617; ClinVar: likely pathogenic; called by mutect2, varscan2
- NDUFS8 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 315/632 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as rs28939679, CM981377; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 389/725 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 85/342 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); catalogued as rs141434302; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4095C>A p.Y1365* | Nonsense Mutation (SNP) | VAF 49/137 reads (36%) | catalogued as COSV54438086; called by muse, mutect2, varscan2
- AGO1 | c.1807G>C p.D603H | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594773; called by muse, mutect2, varscan2
- AP2A2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 46/114 reads (40%) | catalogued as rs1387497180; called by muse, mutect2, varscan2
- APLP1 | c.1272G>C p.Q424H | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55701580; called by muse, mutect2, varscan2
- AVPR1A | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54547673; called by muse, mutect2, varscan2
- BAIAP2L1 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50059560; called by muse, mutect2, varscan2
- C3orf20 | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1559394383; called by muse, mutect2, varscan2
- CCDC146 | c.2656_2657del p.K886Vfs*9 | Frame Shift Del (DEL) | VAF 44/279 reads (16%) | catalogued as rs1443772091; called by mutect2, pindel, varscan2
- CEP135 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99954913; called by muse, mutect2, varscan2
- DENND4C | c.5535G>T p.K1845N (on ENST00000434457 / NM_001330640.2; = p.K1796N on NM_017925.7) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.691); catalogued as COSV63008415; called by muse, mutect2, varscan2
- DNAAF1 | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV100499781; called by muse, mutect2
- EIF3A | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 79/330 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs745318119; called by muse, mutect2, varscan2
- EIF3L | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763759372; called by muse, mutect2, varscan2
- ENAH | c.1561C>G p.Q521E | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.142); catalogued as rs866884146; called by muse, mutect2
- FPGT | c.1416G>C p.K472N | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV100907073; called by muse, mutect2, varscan2
- GNAS | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as rs758121962, COSV58339834, COSV58341404; called by muse, mutect2, varscan2
- GTF2F1 | c.1193C>G p.S398C | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs758541092; called by muse, mutect2, varscan2
- H3C13 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 88/562 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58944655; called by muse, mutect2, varscan2
- HECTD1 | c.7427A>C p.E2476A | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as rs764095323; called by muse, mutect2, varscan2
- HMCN1 | c.7640G>A p.R2547K | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV99634598; called by muse, mutect2
- HMG20B | c.678C>G p.S226R | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs773326341; called by muse, mutect2, varscan2
- IL6ST | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV61140498, COSV61141939; called by muse, mutect2, varscan2
- IQGAP3 | c.4282C>G p.H1428D | Missense Mutation (SNP) | VAF 113/805 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63254256; called by muse, mutect2, varscan2
- KCNH8 | c.552C>G p.N184K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV60473728; called by muse, mutect2, varscan2
- KCNMA1 | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.071); catalogued as COSV54253141; called by mutect2, varscan2
- KIF13B | c.4462G>A p.V1488M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.681); catalogued as rs199652125; called by mutect2, varscan2
- LNPK | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV55824327; called by muse, mutect2, varscan2
- MAN2B1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 146/574 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1312728452, COSV54418028; called by muse, varscan2
- MAP1S | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV60721565; called by muse, mutect2, varscan2
- MAPKAPK2 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs1553432760; called by mutect2, varscan2
- NHLRC2 | c.1648G>C p.D550H | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs998364961; called by muse, mutect2, varscan2
- NMD3 | c.496A>T p.K166* | Nonsense Mutation (SNP) | VAF 28/132 reads (21%) | catalogued as rs1362168746; called by muse, mutect2, varscan2
- NOL3 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs902026689; called by muse, mutect2
- NOTCH3 | c.4868C>T p.P1623L | Missense Mutation (SNP) | VAF 229/471 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs774169388, COSV54630158; called by muse, mutect2, varscan2
- NOTCH4 | c.5506G>C p.E1836Q | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as COSV66679424, COSV66679988, COSV66681239; called by muse, mutect2, varscan2
- OXTR | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as COSV99071423; called by muse, mutect2
- PEAK1 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.326); catalogued as COSV56944000; called by muse, mutect2, varscan2
- PITPNM2 | c.3358G>A p.V1120M | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs147284580; called by muse, mutect2, varscan2
- PKDREJ | c.4096C>G p.L1366V | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1248714198, COSV53549083; called by muse, mutect2, varscan2
- PLCH2 | c.357C>G p.N119K | Missense Mutation (SNP) | VAF 238/452 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs773605621; called by muse, mutect2, varscan2
- PLPPR3 | c.1332_1334del p.E447del (on ENST00000520876 / NM_001270366.2; = p.E475del on NM_024888.2) | In Frame Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs1296371570; called by mutect2, varscan2
- PPL | c.4139G>A p.R1380Q | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs777290550, COSV52170574; called by muse, mutect2, varscan2
- PSG1 | c.723G>C p.K241N | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs759290841; called by muse, mutect2, varscan2
- PSIP1 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1425578383, COSV101051000; called by muse, mutect2, varscan2
- RNF149 | c.713G>C p.S238T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV54863816; called by muse, mutect2, varscan2
- RTL1 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66016860; called by muse, mutect2, varscan2
- SARDH | c.1456G>C p.D486H | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1419111592; called by muse, mutect2, varscan2
- SLC24A3 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV60114000; called by muse, mutect2, varscan2
- SNIP1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as rs1462607966, COSV99953028; called by muse, mutect2, varscan2
- SP8 | c.1051C>G p.R351G (on ENST00000361443 / NM_198956.4; = p.R369G on NM_182700.6) | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV63866080; called by muse, mutect2, varscan2
- SPINT1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 101/414 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs371706199; called by muse, mutect2, varscan2
- TAF4B | c.1424C>G p.S475* | Nonsense Mutation (SNP) | VAF 45/338 reads (13%) | catalogued as COSV52311229; called by muse, mutect2, varscan2
- TBC1D4 | c.1370C>G p.P457R | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66487991, COSV66489513; called by muse, mutect2, varscan2
- TLN2 | c.4006C>G p.L1336V | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.335); catalogued as COSV100169169; called by muse, mutect2, varscan2
- YEATS2 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs919530192; called by muse, mutect2, varscan2
- ZFHX3 | c.5822G>C p.R1941T | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1398563308; called by muse, mutect2, varscan2
- ZNF439 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV58309010, COSV58309542; called by muse, mutect2, varscan2
- ZNF585A | c.386C>G p.A129G (on ENST00000292841 / NM_001288800.2; = p.A74G on NM_152655.3) | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV53061843; called by muse, mutect2, varscan2
- ZNF836 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.952); catalogued as rs371268827; called by muse, mutect2, varscan2
- ZNF862 | c.2329_2331del p.E777del | In Frame Del (DEL) | VAF 73/218 reads (33%) | catalogued as rs780103235; called by mutect2, pindel, varscan2
- ABCA13 | c.1703C>A p.S568* | Nonsense Mutation (SNP) | VAF 30/146 reads (21%) | called by mutect2, varscan2
- ABCA13 | c.2936A>C p.Q979P | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ABHD15 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- AC007040.2 | c.11T>C p.M4T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.12112G>C p.E4038Q | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AFF3 | c.726T>A p.D242E | Missense Mutation (SNP) | VAF 68/396 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.214); called by muse, varscan2
- AGAP5 | c.1701C>G p.I567M | Missense Mutation (SNP) | VAF 211/610 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AHNAK | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- AKAP6 | c.4423G>T p.G1475C | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALMS1 | c.9540-1G>C p.X3180_splice | Splice Site (SNP) | VAF 57/251 reads (23%) | called by muse, mutect2, varscan2
- ALPK2 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 86/440 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANGPT1 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3017G>T p.R1006I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANKRD34C | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ANKRD44 | c.2183C>G p.S728* | Nonsense Mutation (SNP) | VAF 94/338 reads (28%) | called by muse, mutect2, varscan2
- ANO7 | c.211G>A p.V71M (on ENST00000274979; = p.V17M on NM_001001666.4) | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARIH2 | c.487A>C p.S163R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by mutect2, varscan2
- ASPSCR1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, mutect2
- ATP2B3 | c.3287A>T p.E1096V | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ATP6V0A1 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); called by muse, mutect2
- AUTS2 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BNIP5 | c.595G>C p.G199R | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- BOD1L1 | c.3584A>T p.K1195M | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- BTBD9 | c.1690_1692del p.K564del | In Frame Del (DEL) | VAF 57/302 reads (19%) | called by mutect2, pindel, varscan2
- C1S | c.1362_1364del p.F455del | In Frame Del (DEL) | VAF 91/472 reads (19%) | called by pindel, varscan2
- CBX3 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CELSR2 | c.7316_7330del p.C2439_I2444delinsF | In Frame Del (DEL) | VAF 59/126 reads (47%) | called by mutect2, pindel, varscan2
- CENPO | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CHL1 | c.607T>G p.C203G | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CKLF | c.423G>T p.Q141H (on ENST00000264001 / NM_016951.4; = p.Q56H on NM_016326.3) | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CLK1 | c.1179G>C p.R393S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- COL4A1 | c.4196G>C p.G1399A | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPT1B | c.698_699del p.Y233Cfs*3 | Frame Shift Del (DEL) | VAF 68/336 reads (20%) | called by mutect2, pindel, varscan2
- CSGALNACT2 | c.1302G>C p.M434I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CSPP1 | c.3368_3369insGCT p.L1124dup (on ENST00000676605; = p.L1083dup on NM_024790.6) | In Frame Ins (INS) | VAF 33/126 reads (26%) | called by mutect2, pindel, varscan2
- CTDNEP1 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTTN | c.458-1G>T p.X153_splice | Splice Site (SNP) | VAF 27/268 reads (10%) | called by muse, mutect2
- CYB5D1 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYTH2 | c.353+8C>G | Splice Region (SNP) | VAF 70/185 reads (38%) | called by mutect2, varscan2
- DEPDC1 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DEPDC1 | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DGKQ | c.1975_1977del p.E659del | In Frame Del (DEL) | VAF 28/110 reads (25%) | called by pindel, varscan2
- DMTF1 | c.1380_1385delinsCCCAAG p.L461_Q462delinsPR | Missense Mutation (ONP) | VAF 28/123 reads (23%) | called by pindel, varscan2*
- DOP1A | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- DST | c.16134G>C p.K5378N (on ENST00000361203 / NM_001374722.1; = p.K2966N on NM_015548.5) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); called by muse, mutect2
- EFNB3 | c.350T>A p.F117Y | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EIF4G3 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EPB41L1 | c.1389del p.Q464Nfs*19 | Frame Shift Del (DEL) | VAF 116/474 reads (24%) | called by mutect2, varscan2
- EXTL1 | c.1535T>G p.L512R | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM193A | c.3641_3642del p.K1214Rfs*3 (on ENST00000324666 / NM_001256666.1; = p.K1173Rfs*3 on NM_003704.3) | Frame Shift Del (DEL) | VAF 15/125 reads (12%) | called by mutect2, pindel, varscan2
- FMR1NB | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GABBR1 | c.1752C>G p.F584L | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- GADL1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GALR1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDAP1 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 142/448 reads (32%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GDF6 | c.963T>G p.D321E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GFUS | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GJA4 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GPATCH8 | c.3502A>T p.R1168W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- GPC2 | c.192G>C p.Q64H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GPR173 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 120/326 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- GTSE1 | c.2045T>C p.V682A | Missense Mutation (SNP) | VAF 116/548 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HEXB | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HIRA | c.2849-1G>C p.X950_splice | Splice Site (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- HNRNPL | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 74/632 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HPN | c.820del p.Q274Sfs*20 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- ICAM5 | c.74_80del p.G25Efs*27 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel*, varscan2*
- IDH1 | c.1031del p.A344Efs*29 | Frame Shift Del (DEL) | VAF 88/358 reads (25%) | called by mutect2, pindel, varscan2
- IGKV2-28 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- IGLV4-3 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 125/660 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGSF9 | c.2807A>G p.N936S (on ENST00000368094 / NM_001135050.2; = p.N920S on NM_020789.4) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.1); called by muse, mutect2
- IKZF3 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ILF3 | c.690C>G p.I230M | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- INPP5F | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- INPP5J | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2
- IP6K1 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IQSEC1 | c.161G>C p.S54T | Missense Mutation (SNP) | VAF 83/424 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ITGA5 | c.465A>C p.A155= | Splice Region (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- KCNC4 | c.1381G>T p.V461L | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- KCNH1 | c.1664T>A p.V555D (on ENST00000271751 / NM_172362.3; = p.V528D on NM_002238.4) | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- KIAA1109 | c.3820G>C p.D1274H | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- KIAA1614 | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIRREL3 | c.231_266del p.F77_V89delinsL | In Frame Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- KLHL21 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KLHL5 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT25 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LAMA3 | c.3793C>T p.P1265S | Missense Mutation (SNP) | VAF 135/529 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCA5 | c.1550G>C p.R517T | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LDB2 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LECT2 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LMLN2 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.859); called by muse, mutect2
- LRRC8E | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- LRRTM4 | c.1395_1414del p.R466Vfs*2 | Frame Shift Del (DEL) | VAF 41/281 reads (15%) | called by mutect2, pindel, varscan2
- LTBP4 | c.1856G>C p.R619P (on ENST00000308370 / NM_001042544.1; = p.R582P on NM_003573.2) | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- LYPD8 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- LYPLA2 | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K7 | c.847A>C p.I283L | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MAPK15 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- MARVELD2 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.343); called by muse, mutect2
- MCM4 | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- MROH1 | c.4014G>C p.Q1338H | Missense Mutation (SNP) | VAF 102/800 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by mutect2, varscan2
- MYBPC1 | c.1387A>T p.K463* (on ENST00000550270 / NM_206820.2; = p.K488* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 90/450 reads (20%) | called by mutect2, varscan2
- MYBPH | c.1204T>G p.F402V | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYBPH | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 28/191 reads (15%) | called by mutect2, varscan2
- MZF1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- NAALADL1 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEA | c.6493G>A p.V2165M | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NFKBID | c.82G>A p.E28K (on ENST00000396901; = p.E180K on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NIBAN1 | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 7/210 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2
- NIPSNAP3A | c.153_161del p.F52_E54del | In Frame Del (DEL) | VAF 95/362 reads (26%) | called by mutect2, pindel, varscan2
- NLGN1 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NLRP7 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 234/437 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NOL12 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- NOTCH1 | c.5549C>T p.A1850V | Missense Mutation (SNP) | VAF 152/588 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- NT5C2 | c.316_319del p.Y106Efs*4 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- NUBP1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NUP62CL | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODF3B | c.171C>A p.F57L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, varscan2
- OR10W1 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 102/433 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- OR1S1 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 89/396 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2B11 | c.328T>A p.W110R | Missense Mutation (SNP) | VAF 83/342 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- OR2W3 | c.249del p.Y83* | Frame Shift Del (DEL) | VAF 30/219 reads (14%) | called by mutect2, pindel, varscan2
- OR4A5 | c.387C>G p.H129Q | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.285); called by mutect2, varscan2
- OVGP1 | c.1694G>C p.R565T | Missense Mutation (SNP) | VAF 107/192 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- OXSR1 | c.909A>T p.K303N | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- PABPC5 | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCBP2 | c.1098G>C p.*366Yext*24 (on ENST00000439930 / NM_001128911.2; = p.*367Yext*24 on NM_005016.6) | Nonstop Mutation (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- PCDHB10 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PDE4B | c.1476_1477del p.C492* | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | called by pindel, varscan2
- PDGFRA | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PGR | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- PHF21B | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PKD1L1 | c.5932G>A p.G1978R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- PKHD1 | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PPIP5K1 | c.3873G>C p.E1291D (on ENST00000396923; = p.E1266D on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, varscan2
- PPP6R1 | c.2277C>A p.S759R | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2
- PPP6R3 | c.2571G>C p.R857S (on ENST00000393800 / NM_001352375.2; = p.R777S on NM_018312.5) | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN12 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTPRO | c.2736G>C p.R912S (on ENST00000281171 / NM_030667.3; = p.R884S on NM_002848.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, varscan2
- RAB4B | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RANBP17 | c.1438G>C p.G480R | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASD1 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- RASGRP3 | c.1495_1497del p.E499del (on ENST00000402538 / NM_001349975.2; = p.E498del on NM_015376.2 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 34/111 reads (31%) | called by mutect2, pindel, varscan2
- RBM4B | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 137/703 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- RIBC2 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIPOR2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RNF215 | c.488del p.N163Tfs*16 | Frame Shift Del (DEL) | VAF 51/249 reads (20%) | called by mutect2, pindel, varscan2
- RPS6KA3 | c.1373_1376del p.R458Tfs*21 | Frame Shift Del (DEL) | VAF 95/278 reads (34%) | called by mutect2, pindel, varscan2
- RSF1 | c.2389G>C p.D797H | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- RSL24D1 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- SAMD9 | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- SEC31A | c.403-1G>A p.X135_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2
- SELENOV | c.1037G>T p.R346M | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SELPLG | c.1153_1185del p.S385_E395del | In Frame Del (DEL) | VAF 31/120 reads (26%) | called by mutect2, pindel, varscan2
- SEMA7A | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 95/540 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETBP1 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 91/724 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- SETMAR | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SMARCA4 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SMG8 | c.1068G>C p.R356S | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SOCS3 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SSX2IP | c.44-13_54del p.X15_splice | Splice Site (DEL) | VAF 10/122 reads (8%) | called by mutect2, pindel
- STAT2 | c.1785_1786del p.G596Hfs*8 | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | called by mutect2, pindel, varscan2
- STK10 | c.2553G>T p.Q851H | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by mutect2, varscan2
- STK11IP | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STX4 | c.696G>C p.E232D | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SYNCRIP | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- TAF15 | c.1510G>C p.D504H (on ENST00000605844 / NM_139215.3; = p.D501H on NM_003487.4) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- TBP | c.200_201insACA p.Q95dup | In Frame Ins (INS) | VAF 91/258 reads (35%) | called by mutect2, pindel, varscan2
- TBXT | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TEX15 | c.7594G>A p.V2532I (on ENST00000256246; = p.V2915I on NM_001350162.2) | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TNN | c.2188C>A p.P730T | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by mutect2, varscan2
- TNPO3 | c.2359G>C p.D787H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- TNRC6C | c.2683G>T p.D895Y | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM17 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- TSNARE1 | c.970C>G p.R324G | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TSPOAP1 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 38/588 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.76); called by muse, mutect2
- TTC12 | c.1308+1G>A p.X436_splice | Splice Site (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- TTLL7 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- UEVLD | c.1091_1092del p.V364Efs*32 (on ENST00000396197 / NM_001040697.4; = p.V364Efs*67 on NM_018314.6) | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- UMODL1 | c.521C>G p.T174S | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- UQCRH | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- VSIG8 | c.222_223del p.N75Rfs*4 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | called by pindel, varscan2
- WDR62 | c.4251C>G p.H1417Q | Missense Mutation (SNP) | VAF 46/951 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- ZBTB47 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2
- ZFHX2 | c.4487A>T p.K1496M | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZKSCAN2 | c.2735A>G p.E912G | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF263 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ZNF444 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ZNF514 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ZNF585A | c.553C>G p.P185A (on ENST00000292841 / NM_001288800.2; = p.P130A on NM_152655.3) | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZNF703 | c.550T>C p.S184P | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ZPBP | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ADCY8 | c.2355G>C p.R785= | Silent (SNP) | VAF 69/469 reads (15%) | called by muse, mutect2, varscan2
- ANAPC2 | c.2400G>A p.Q800= | Silent (SNP) | VAF 41/207 reads (20%) | catalogued as rs759338384; called by muse, mutect2, varscan2
- AOC3 | c.2172C>T p.Y724= | Silent (SNP) | VAF 61/266 reads (23%) | called by muse, mutect2, varscan2
- ASIC4 | c.945G>T p.V315= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as rs1252570847; called by muse, mutect2
- CA3 | c.600G>A p.P200= | Silent (SNP) | VAF 44/196 reads (22%) | catalogued as rs562539925, COSV53409696; called by muse, mutect2, varscan2
- CABIN1 | c.2157T>C p.S719= | Silent (SNP) | VAF 103/661 reads (16%) | catalogued as rs745759224; called by muse, mutect2, varscan2
- CADM1 | c.1140C>T p.V380= | Silent (SNP) | VAF 111/317 reads (35%) | catalogued as rs757194461, COSV100523239; called by muse, mutect2, varscan2
- CCDC114 | c.111C>T p.I37= | Silent (SNP) | VAF 41/165 reads (25%) | called by muse, mutect2, varscan2
- CDH26 | c.519T>C p.T173= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs1458220905; called by muse, mutect2, varscan2
- COL6A5 | c.3459A>C p.I1153= | Silent (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- DHCR7 | c.312C>T p.V104= | Silent (SNP) | VAF 39/244 reads (16%) | called by muse, mutect2, varscan2
- EFCAB9 | c.423C>G p.L141= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV67960547; called by muse, mutect2, varscan2
- ERN2 | c.276C>T p.I92= | Silent (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- FABP7 | c.81C>G p.G27= | Silent (SNP) | VAF 27/185 reads (15%) | catalogued as rs1257505369; called by muse, mutect2, varscan2
- FAM186B | c.204G>A p.Q68= | Silent (SNP) | VAF 40/386 reads (10%) | called by muse, mutect2
- GRIK5 | c.1467C>A p.I489= | Silent (SNP) | VAF 37/203 reads (18%) | called by muse, mutect2, varscan2
- H4C2 | c.291T>A p.T97= | Silent (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- H4C2 | c.198G>C p.V66= | Silent (SNP) | VAF 86/290 reads (30%) | catalogued as COSV55140871, COSV99774872, COSV99775131; called by muse, varscan2
- H4C5 | c.213G>C p.V71= | Silent (SNP) | VAF 39/221 reads (18%) | catalogued as COSV63486292; called by muse, mutect2, varscan2
- HFM1 | c.363G>A p.L121= | Silent (SNP) | VAF 47/248 reads (19%) | called by muse, mutect2, varscan2
- HNRNPK | c.894C>T p.G298= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV100698957; called by muse, mutect2, varscan2
- IGLV7-46 | c.72T>C p.T24= | Silent (SNP) | VAF 57/299 reads (19%) | catalogued as rs1319194064; called by muse, mutect2, varscan2
- IMPG2 | c.2532G>C p.R844= | Silent (SNP) | VAF 122/563 reads (22%) | called by muse, mutect2, varscan2
- KIF9 | c.1986G>A p.K662= (on ENST00000265529 / NM_001377474.1; = p.K597= on NM_022342.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- LENG8 | c.1887G>A p.R629= | Silent (SNP) | VAF 57/373 reads (15%) | called by muse, mutect2, varscan2
- LHX4 | c.789T>C p.I263= | Silent (SNP) | VAF 92/387 reads (24%) | called by muse, mutect2, varscan2
- MON1A | c.1953C>G p.T651= | Silent (SNP) | VAF 38/142 reads (27%) | called by mutect2, varscan2
- MRC2 | c.2094C>G p.V698= | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- MYBPC3 | c.2430C>G p.R810= | Silent (SNP) | VAF 46/255 reads (18%) | called by mutect2, varscan2
- NAV3 | c.1893A>G p.A631= | Silent (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- NKD2 | c.852C>T p.S284= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs767070749; called by muse, mutect2, varscan2
- NOA1 | c.1245A>G p.E415= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV99950411; called by muse, mutect2, varscan2
- OLFM2 | c.384A>G p.E128= | Silent (SNP) | VAF 38/405 reads (9%) | called by muse, mutect2, varscan2
- OR56A5 | c.45C>T p.F15= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV60827443; called by muse, mutect2
- PIGN | c.2352C>T p.I784= | Silent (SNP) | VAF 73/202 reads (36%) | called by muse, mutect2, varscan2
- PLA2G4E | c.882C>A p.P294= | Silent (SNP) | VAF 55/208 reads (26%) | called by muse, mutect2, varscan2
- PLCD3 | c.2001G>A p.L667= | Silent (SNP) | VAF 40/172 reads (23%) | called by muse, mutect2, varscan2
- PPM1L | c.582G>A p.T194= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs769707582; called by muse, mutect2, varscan2
- RAB23 | c.657C>G p.P219= | Silent (SNP) | VAF 105/447 reads (23%) | called by muse, mutect2, varscan2
- RABEP2 | c.1623G>C p.R541= | Silent (SNP) | VAF 37/131 reads (28%) | called by muse, mutect2, varscan2
- RFPL2 | c.435C>G p.V145= | Silent (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2
- RTCB | c.291G>A p.G97= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- SAMSN1 | c.588C>T p.N196= | Silent (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- SF3B3 | c.3066C>T p.I1022= | Silent (SNP) | VAF 102/379 reads (27%) | called by muse, mutect2, varscan2
- SLC12A4 | c.2775G>C p.R925= | Silent (SNP) | VAF 64/224 reads (29%) | called by muse, mutect2, varscan2
- SLC35F6 | c.531C>T p.I177= | Silent (SNP) | VAF 71/249 reads (29%) | called by muse, mutect2, varscan2
- SLC3A2 | c.855C>G p.G285= | Silent (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- SRBD1 | c.2823G>A p.G941= | Silent (SNP) | VAF 112/321 reads (35%) | called by muse, mutect2, varscan2
- STEAP2 | c.1461C>G p.V487= | Silent (SNP) | VAF 41/212 reads (19%) | called by muse, mutect2, varscan2
- SWAP70 | c.291C>T p.L97= | Silent (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- ZNF484 | c.1428C>G p.V476= | Silent (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- ZNF571 | c.738A>T p.T246= | Silent (SNP) | VAF 127/258 reads (49%) | called by mutect2, varscan2
- AC024940.1 | n.5167C>T | RNA (SNP) | VAF 47/198 reads (24%) | called by muse, mutect2, varscan2
- ACCS | c.349-29C>G | Intron (SNP) | VAF 40/204 reads (20%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29701757 C>G | 3'Flank (SNP) | VAF 94/288 reads (33%) | called by muse, varscan2
- CD81 | c.67-3826G>C | Intron (SNP) | VAF 54/163 reads (33%) | called by muse, mutect2, varscan2
- CDC42 | c.487-1414G>T | Intron (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- CEP170P1 | n.2021C>G | RNA (SNP) | VAF 35/352 reads (10%) | called by muse, mutect2
- CYB5RL | chr1:54171450 G>C | 3'Flank (SNP) | VAF 39/179 reads (22%) | called by muse, mutect2, varscan2
- DST | c.4297-2661G>C | Intron (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
- EIF4A2 | c.1079+433G>C | Intron (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | chr7:73269261 C>G | 5'Flank (SNP) | VAF 68/457 reads (15%) | called by muse, mutect2, varscan2
- HPN | c.161-77G>C | Intron (SNP) | VAF 30/216 reads (14%) | called by mutect2, varscan2
- IFT22 | c.40-18T>C | Intron (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- IL7R | c.801-54G>A | Intron (SNP) | VAF 50/205 reads (24%) | catalogued as rs1463929998; called by muse, mutect2, varscan2
- KCTD1 | c.*49C>G | 3'UTR (SNP) | VAF 22/222 reads (10%) | called by mutect2, varscan2
- KRIT1 | c.2026-49G>A | Intron (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- LSM7 | c.6+32del | Intron (DEL) | VAF 17/135 reads (13%) | called by mutect2, pindel, varscan2
- MIF4GD | chr17:75272149 C>G | 5'Flank (SNP) | VAF 34/193 reads (18%) | called by muse, mutect2, varscan2
- MXD3 | chr5:177307136 del TAT | 3'Flank (DEL) | VAF 30/93 reads (32%) | catalogued as rs1414527144; called by pindel, varscan2
- MYH7B | c.2100+102G>T | Intron (SNP) | VAF 71/282 reads (25%) | called by muse, mutect2, varscan2
- NT5E | c.*12C>G | 3'UTR (SNP) | VAF 51/299 reads (17%) | called by muse, mutect2, varscan2
- PDZRN3 | c.918+33169C>T | Intron (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- PFKM | c.1500+36C>G | Intron (SNP) | VAF 125/367 reads (34%) | called by muse, mutect2, varscan2
- PKM | c.565+10G>C | Intron (SNP) | VAF 55/303 reads (18%) | catalogued as COSV58789099; called by muse, mutect2, varscan2
- PLAGL2 | chr20:32189541 C>T | 3'Flank (SNP) | VAF 103/376 reads (27%) | called by muse, mutect2, varscan2
- PPP1R1B | c.143-93T>A | Intron (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- PRR29 | c.60+13C>A | Intron (SNP) | VAF 15/56 reads (27%) | catalogued as rs1169058622; called by muse, mutect2, varscan2
- RGS11 | c.658-35C>T | Intron (SNP) | VAF 82/242 reads (34%) | called by muse, mutect2, varscan2
- RNF32 | c.853-100G>C | Intron (SNP) | VAF 58/239 reads (24%) | called by muse, mutect2, varscan2
- SLC25A38 | c.-47C>T | 5'UTR (SNP) | VAF 56/159 reads (35%) | catalogued as rs371816810; called by muse, mutect2, varscan2
- SSPOP | n.14277C>A | RNA (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | chr17:76563147 C>T | 3'Flank (SNP) | VAF 45/244 reads (18%) | called by muse, mutect2, varscan2
- TAAR3P | n.201C>G | RNA (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- TTC19 | c.*873G>T | 3'UTR (SNP) | VAF 121/530 reads (23%) | called by muse, mutect2, varscan2
- TYMP | c.215-34G>C | Intron (SNP) | VAF 113/467 reads (24%) | called by muse, mutect2, varscan2
- ZNF781 | c.*71T>G | 3'UTR (SNP) | VAF 39/225 reads (17%) | catalogued as rs1406409272; called by muse, mutect2, varscan2
